Somatic mutation profile of cancer-model specimen HCM-CSHL-0622-C18-85A (3D Organoid, passage 5; aliquot HCM-CSHL-0622-C18-85A-01D-A82H-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0622-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: GX; Age at diagnosis: 78.3 years (28,592 days).
Specimen HCM-CSHL-0622-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26062ba2-1089-4646-93db-ca3e6d27a0c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0622-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0622-C18-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74fb42d5-c8b5-4c3c-931c-fbf0549af7c2

The open-access MAF lists 188 somatic variants for this specimen: 129 protein-altering or splice-affecting, 48 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 48, Nonsense Mutation 8, Intron 8, Frame Shift Ins 5, 5'Flank 2, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 180/300 reads (60%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 216/337 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.331A>G p.K111E | Missense Mutation (SNP) | VAF 142/214 reads (66%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1057519933, COSV55878486, COSV56029794; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 356/357 reads (100%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ACVR1B | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 303/303 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1460557299, COSV57776372, COSV57780549; called by muse, mutect2, varscan2
- ADGRG5 | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 241/373 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.371); catalogued as rs370948921; called by muse, mutect2, varscan2
- AGPAT2 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 208/793 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs751365063; called by muse, mutect2, varscan2
- AGTR2 | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 191/464 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as rs782693661, COSV100903587; called by muse, mutect2, varscan2
- ALDH1L1 | c.2012C>T p.S671F | Missense Mutation (SNP) | VAF 89/307 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1353099444; called by muse, mutect2, varscan2
- ARID1A | c.1850C>A p.S617* | Nonsense Mutation (SNP) | VAF 149/366 reads (41%) | catalogued as COSV61374388, COSV61381125; called by muse, mutect2, varscan2
- ASH1L | c.7670T>C p.I2557T (on ENST00000368346 / NM_001366177.2; = p.I2552T on NM_018489.3) | Missense Mutation (SNP) | VAF 324/591 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV64210323; called by muse, mutect2, varscan2
- ATG12 | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 215/215 reads (100%) | catalogued as rs777851308; called by muse, mutect2, varscan2
- B3GNT6 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 302/938 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1555027721; called by muse, mutect2, varscan2
- BRINP1 | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 126/261 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs912181785, COSV56292199; called by muse, mutect2, varscan2
- CDK11B | c.1967C>A p.T656N | Missense Mutation (SNP) | VAF 32/696 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV58340113; called by muse, mutect2
- CFAP47 | c.7532T>C p.L2511P | Missense Mutation (SNP) | VAF 74/388 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1556003441; called by muse, mutect2, varscan2
- CFAP54 | c.1693dup p.I565Nfs*5 | Frame Shift Ins (INS) | VAF 50/141 reads (35%) | catalogued as rs746202185; called by mutect2, varscan2
- CGB5 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 97/398 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.316); catalogued as rs1222317523; called by muse, mutect2, varscan2
- COL4A5 | c.1089G>T p.L363F | Missense Mutation (SNP) | VAF 255/516 reads (49%) | SIFT tolerated (0.7); PolyPhen benign (0.354); catalogued as COSV60372033; called by muse, mutect2, varscan2
- CST9L | c.4C>A p.L2M | Missense Mutation (SNP) | VAF 191/373 reads (51%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV65408054; called by muse, mutect2, varscan2
- CTAGE9 | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 209/549 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1222753640; called by muse, mutect2, varscan2
- DCBLD1 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 38/1064 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1175971851, COSV99757512; called by muse, mutect2
- DCHS2 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 151/342 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as rs1000724585, COSV59719574; called by muse, mutect2, varscan2
- DIRAS1 | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 222/386 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs377045911; called by muse, mutect2, varscan2
- ERV3-1 | c.725A>G p.K242R | Missense Mutation (SNP) | VAF 273/436 reads (63%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1349703987; called by muse, mutect2, varscan2
- FGD1 | c.1867G>A p.V623M | Missense Mutation (SNP) | VAF 264/559 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754355805, COSV64309156; called by muse, mutect2, varscan2
- FLG | c.1324A>T p.K442* | Nonsense Mutation (SNP) | VAF 258/544 reads (47%) | catalogued as COSV64239895; called by muse, mutect2, varscan2
- GALNT2 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 203/406 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761032669, COSV64197744; called by muse, mutect2, varscan2
- GPR50 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 368/745 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs745374692, COSV54440968; called by muse, mutect2, varscan2
- GPSM1 | c.1628C>T p.T543M | Missense Mutation (SNP) | VAF 130/596 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.026); catalogued as rs782268182, COSV52518558; called by muse, mutect2, varscan2
- IFNW1 | c.455T>C p.V152A | Missense Mutation (SNP) | VAF 255/389 reads (66%) | SIFT tolerated (0.05); PolyPhen benign (0.378); catalogued as rs1397365028; called by muse, mutect2, varscan2
- IGF2 | c.313G>A p.G105S (on ENST00000434045 / NM_001127598.3; = p.G49S on NM_000612.6) | Missense Mutation (SNP) | VAF 122/364 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56102221; called by muse, mutect2, varscan2
- INPP4A | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 211/351 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs541626439, COSV99303698; called by muse, mutect2, varscan2
- LPCAT1 | c.1534G>A p.G512S | Missense Mutation (SNP) | VAF 1082/1576 reads (69%) | SIFT tolerated (0.14); PolyPhen benign (0.117); catalogued as COSV99359133; called by muse, mutect2, varscan2
- MAP3K9 | c.2066G>A p.R689H (on ENST00000554752 / NM_001284230.1; = p.R703H on NM_033141.4) | Missense Mutation (SNP) | VAF 251/403 reads (62%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs147124893; called by muse, mutect2, varscan2
- MEX3A | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 350/745 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV68479201; called by muse, varscan2
- MICAL2 | c.2735C>A p.A912D | Missense Mutation (SNP) | VAF 21/461 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV56326356; called by muse, mutect2
- OAS1 | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 425/647 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs776426424; called by muse, mutect2, varscan2
- OR5K4 | c.290G>A p.C97Y | Missense Mutation (SNP) | VAF 112/401 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867737179, COSV100721393; called by muse, mutect2, varscan2
- OR8H2 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 163/457 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57944822, COSV57947162; called by muse, mutect2, varscan2
- OTX2 | c.203G>A p.R68Q (on ENST00000408990 / NM_172337.3; = p.R76Q on NM_021728.4) | Missense Mutation (SNP) | VAF 138/427 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM120938; called by muse, mutect2, varscan2
- PCDH15 | c.1040T>G p.L347R | Missense Mutation (SNP) | VAF 53/223 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57299220, COSV57350026; called by muse, mutect2, varscan2
- PITPNM2 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 219/625 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1487015512; called by muse, mutect2, varscan2
- PKD1L1 | c.7200C>G p.I2400M | Missense Mutation (SNP) | VAF 116/376 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.141); catalogued as rs763959439, COSV51842371; called by muse, mutect2, varscan2
- PKP3 | c.1888G>A p.G630R | Missense Mutation (SNP) | VAF 455/688 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754717193; called by muse, mutect2, varscan2
- PLCL1 | c.2549G>A p.R850Q | Missense Mutation (SNP) | VAF 106/300 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs780231814, COSV70829907; called by muse, mutect2, varscan2
- PTPRK | c.2220C>G p.I740M (on ENST00000368215 / NM_001291984.2; = p.I741M on NM_002844.4) | Missense Mutation (SNP) | VAF 92/413 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.367); catalogued as rs1460178656; called by muse, mutect2, varscan2
- RALGAPB | c.2529G>A p.W843* | Nonsense Mutation (SNP) | VAF 137/291 reads (47%) | catalogued as COSV53434911; called by muse, mutect2, varscan2
- RBMXL3 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 519/1016 reads (51%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs782729732; called by muse, mutect2, varscan2
- RELN | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 81/287 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs772745844, COSV58996502; called by muse, mutect2, varscan2
- ROBO1 | c.4291C>T p.H1431Y | Missense Mutation (SNP) | VAF 15/356 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1454724966; called by muse, mutect2
- RTL3 | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 312/630 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs1045140325; called by muse, mutect2, varscan2
- SCN3A | c.2857G>T p.E953* | Nonsense Mutation (SNP) | VAF 260/409 reads (64%) | catalogued as rs1553522943, COSV99326100; called by muse, mutect2, varscan2
- SH2B3 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 292/928 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.41); catalogued as rs777034332; called by muse, mutect2, varscan2
- SKOR1 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 660/661 reads (100%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs768944790; called by muse, mutect2, varscan2
- SLC16A7 | c.1096G>T p.V366L | Missense Mutation (SNP) | VAF 283/441 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs766022124, COSV99676013; called by muse, mutect2, varscan2
- SMARCA4 | c.3814G>A p.A1272T | Missense Mutation (SNP) | VAF 133/345 reads (39%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.499); catalogued as rs776672640, COSV60810272; called by muse, mutect2, varscan2
- SSH1 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 117/409 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs368822154; called by muse, mutect2, varscan2
- STEAP4 | c.1198G>A p.V400M | Missense Mutation (SNP) | VAF 255/354 reads (72%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs1386830347; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2965G>A p.G989R | Missense Mutation (SNP) | VAF 135/419 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.462); catalogued as rs767424757; called by muse, mutect2, varscan2
- SVEP1 | c.2729C>G p.S910C | Missense Mutation (SNP) | VAF 113/217 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.436); catalogued as rs372821116; called by muse, mutect2, varscan2
- SYNE1 | c.3419T>C p.I1140T (on ENST00000367255 / NM_182961.4; = p.I1147T on NM_033071.3) | Missense Mutation (SNP) | VAF 149/285 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as rs1352916426; called by muse, mutect2, varscan2
- TIGD7 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 27/469 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs766416806, COSV51915420; called by muse, mutect2
- TRIM8 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 334/522 reads (64%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.765); catalogued as rs1217055778; called by muse, mutect2, varscan2
- TRPC4 | c.830T>C p.L277P | Missense Mutation (SNP) | VAF 175/304 reads (58%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs1239748923; called by muse, mutect2, varscan2
- TTN | c.99338C>T p.A33113V (on ENST00000591111; = p.A25689V on NM_003319.4) | Missense Mutation (SNP) | VAF 144/431 reads (33%) | PolyPhen benign (0); catalogued as rs727505020; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.74392C>T p.R24798C (on ENST00000591111; = p.R17374C on NM_003319.4) | Missense Mutation (SNP) | VAF 135/413 reads (33%) | PolyPhen possibly damaging (0.855); catalogued as rs372968732; called by muse, mutect2, varscan2
- TTN | c.10639G>T p.A3547S (on ENST00000591111; = p.A3501S on NM_003319.4) | Missense Mutation (SNP) | VAF 234/354 reads (66%) | catalogued as COSV60397686; called by muse, mutect2, varscan2
- USP16 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 80/250 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.074); catalogued as rs1282539096; called by muse, mutect2, varscan2
- VIT | c.268G>A p.V90I | Missense Mutation (SNP) | VAF 77/306 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs773014347, COSV64895705; called by muse, mutect2, varscan2
- WNK2 | c.4726C>T p.P1576S (on ENST00000297954 / NM_001282394.1; = p.P1539S on NM_006648.3) | Missense Mutation (SNP) | VAF 258/486 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1162335997; called by muse, mutect2, varscan2
- ZNF282 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 324/479 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs760179364, COSV100021841; called by muse, mutect2, varscan2
- ZNF397 | c.352G>T p.G118C | Missense Mutation (SNP) | VAF 257/258 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV54351249; called by muse, mutect2, varscan2
- ZNF479 | c.458A>G p.Q153R | Missense Mutation (SNP) | VAF 11/266 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.165); catalogued as rs781799265; called by muse, mutect2
- ZNF516 | c.1412C>A p.P471Q | Missense Mutation (SNP) | VAF 277/277 reads (100%) | SIFT tolerated (0.51); PolyPhen benign (0.037); catalogued as COSV71586815; called by muse, mutect2, varscan2
- ZNF573 | c.515G>A p.R172H (on ENST00000536220 / NM_001172692.1; = p.R114H on NM_152360.3) | Missense Mutation (SNP) | VAF 102/210 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs184615976; called by muse, mutect2, varscan2
- ABHD12B | c.716C>G p.A239G (on ENST00000337334 / NM_001206673.2; = p.A162G on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/281 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ACTN1 | c.2459C>A p.T820K | Missense Mutation (SNP) | VAF 141/474 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- ASCC3 | c.3891_3892insA p.P1298Tfs*19 | Frame Shift Ins (INS) | VAF 73/215 reads (34%) | called by mutect2, pindel, varscan2
- CACUL1 | c.1069A>G p.N357D | Missense Mutation (SNP) | VAF 226/312 reads (72%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- CALCRL | c.1137G>T p.L379F | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.387); called by muse, mutect2
- CHD4 | c.3601G>A p.E1201K (on ENST00000357008 / NM_001363606.2; = p.E1214K on NM_001273.5) | Missense Mutation (SNP) | VAF 146/454 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CHSY3 | c.1895A>C p.D632A | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CLEC12B | c.730T>C p.Y244H | Missense Mutation (SNP) | VAF 146/226 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- COL28A1 | c.1745C>G p.P582R | Missense Mutation (SNP) | VAF 251/413 reads (61%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- COL2A1 | c.3730G>A p.A1244T | Missense Mutation (SNP) | VAF 460/667 reads (69%) | SIFT tolerated (0.16); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CRYZ | c.457C>G p.L153V | Missense Mutation (SNP) | VAF 186/186 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DICER1 | c.3544C>G p.Q1182E | Missense Mutation (SNP) | VAF 104/287 reads (36%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJB5 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 165/534 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- DOCK4 | c.5762C>T p.S1921F | Missense Mutation (SNP) | VAF 212/644 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- ENTPD1 | c.895A>G p.T299A | Missense Mutation (SNP) | VAF 287/450 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FANCL | c.281C>A p.A94D | Missense Mutation (SNP) | VAF 63/234 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- FBXO43 | c.996A>C p.E332D | Missense Mutation (SNP) | VAF 18/479 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.048); called by muse, mutect2
- FBXW7 | c.1943T>G p.L648R (on ENST00000281708 / NM_001349798.2; = p.L568R on NM_018315.5) | Missense Mutation (SNP) | VAF 319/319 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FCMR | c.433C>G p.P145A | Missense Mutation (SNP) | VAF 75/438 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- FKBP8 | c.173dup p.M58Ifs*10 | Frame Shift Ins (INS) | VAF 278/644 reads (43%) | called by mutect2, pindel, varscan2
- FMN2 | c.4993T>C p.W1665R | Missense Mutation (SNP) | VAF 243/441 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FNDC1 | c.4129C>G p.H1377D | Missense Mutation (SNP) | VAF 179/341 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- HMCN1 | c.7853C>G p.S2618C | Missense Mutation (SNP) | VAF 131/282 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HUS1 | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 280/442 reads (63%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNK18 | c.155C>A p.A52E | Missense Mutation (SNP) | VAF 130/409 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KLHL34 | c.1433T>C p.I478T | Missense Mutation (SNP) | VAF 208/1036 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LARGE2 | c.2079C>G p.F693L | Missense Mutation (SNP) | VAF 211/657 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- LDLR | c.2490G>C p.K830N | Missense Mutation (SNP) | VAF 123/335 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MMP12 | c.1138dup p.I380Nfs*2 | Frame Shift Ins (INS) | VAF 158/256 reads (62%) | called by mutect2, varscan2
- NSD3 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 110/240 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NUTM2D | c.2275G>C p.E759Q | Missense Mutation (SNP) | VAF 224/706 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- OR13C3 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 98/217 reads (45%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- OR13G1 | c.523T>G p.F175V | Missense Mutation (SNP) | VAF 21/709 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.861); called by muse, mutect2
- PAX8 | c.84A>C p.E28D | Missense Mutation (SNP) | VAF 20/666 reads (3%) | SIFT tolerated (1); PolyPhen probably damaging (0.927); called by muse, mutect2
- PLXND1 | c.3295A>G p.N1099D | Missense Mutation (SNP) | VAF 196/693 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- PML | c.2473C>T p.R825C | Missense Mutation (SNP) | VAF 442/442 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRSS37 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 75/373 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RBMXL2 | c.157T>G p.F53V | Missense Mutation (SNP) | VAF 293/456 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- RIMS4 | c.340A>G p.T114A | Missense Mutation (SNP) | VAF 251/529 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SCML2 | c.368A>C p.K123T | Missense Mutation (SNP) | VAF 30/648 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- SCN3A | c.2856G>T p.M952I | Missense Mutation (SNP) | VAF 261/410 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SELENOT | c.430A>T p.M144L | Missense Mutation (SNP) | VAF 143/236 reads (61%) | SIFT tolerated (0.78); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SERF2 | c.61T>C p.S21P | Missense Mutation (SNP) | VAF 214/214 reads (100%) | SIFT tolerated (0.29); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- SYNE1 | c.3800A>C p.N1267T (on ENST00000367255 / NM_182961.4; = p.N1274T on NM_033071.3) | Missense Mutation (SNP) | VAF 12/358 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- TBC1D9 | c.937T>C p.C313R | Missense Mutation (SNP) | VAF 161/375 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TBR1 | c.1610G>A p.G537D | Missense Mutation (SNP) | VAF 45/934 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2
- TCF12 | c.1396-1G>C p.X466_splice | Splice Site (SNP) | VAF 159/159 reads (100%) | called by muse, mutect2, varscan2
- TCF7 | c.1268A>G p.Y423C | Missense Mutation (SNP) | VAF 400/400 reads (100%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TEX13C | c.2099A>G p.K700R | Missense Mutation (SNP) | VAF 393/928 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); called by muse, varscan2
- TFCP2 | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 22/434 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2
- TMEM200C | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 330/330 reads (100%) | called by muse, mutect2, varscan2
- WIPF1 | c.475A>C p.S159R | Missense Mutation (SNP) | VAF 139/515 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF182 | c.708T>A p.C236* | Nonsense Mutation (SNP) | VAF 219/477 reads (46%) | called by muse, mutect2, varscan2
- ADGRG4 | c.5605A>C p.R1869= | Silent (SNP) | VAF 42/790 reads (5%) | catalogued as COSV54961513, COSV99794566; called by muse, mutect2
- ADH1C | c.537T>A p.T179= | Silent (SNP) | VAF 78/241 reads (32%) | called by muse, mutect2, varscan2
- AFF3 | c.2001G>A p.E667= | Silent (SNP) | VAF 328/521 reads (63%) | called by muse, mutect2
- ARSF | c.714G>A p.T238= | Silent (SNP) | VAF 370/797 reads (46%) | catalogued as rs764936345, COSV63840977; called by muse, varscan2
- ATRN | c.807T>C p.V269= | Silent (SNP) | VAF 274/556 reads (49%) | called by muse, mutect2, varscan2
- BIRC6 | c.11043C>T p.D3681= | Silent (SNP) | VAF 102/332 reads (31%) | catalogued as rs1259262043; called by muse, mutect2, varscan2
- C17orf64 | c.417G>A p.P139= | Silent (SNP) | VAF 238/238 reads (100%) | catalogued as rs138750913; called by muse, mutect2, varscan2
- CCKBR | c.1068C>T p.R356= | Silent (SNP) | VAF 360/537 reads (67%) | catalogued as rs535599390, COSV58100734; called by muse, mutect2, varscan2
- CDC42EP4 | c.375G>A p.K125= | Silent (SNP) | VAF 379/380 reads (100%) | called by muse, mutect2, varscan2
- CFLAR | c.1146T>C p.N382= | Silent (SNP) | VAF 292/434 reads (67%) | called by muse, mutect2, varscan2
- CPQ | c.549G>A p.T183= | Silent (SNP) | VAF 184/325 reads (57%) | catalogued as rs201427497; called by muse, mutect2, varscan2
- EVC | c.2880C>T p.T960= | Silent (SNP) | VAF 105/197 reads (53%) | catalogued as rs1321237358; called by muse, mutect2, varscan2
- FAM135B | c.1314A>C p.I438= | Silent (SNP) | VAF 88/269 reads (33%) | called by muse, mutect2, varscan2
- FAM90A26 | c.1077C>T p.V359= | Silent (SNP) | VAF 200/200 reads (100%) | catalogued as rs765831190; called by muse, mutect2, varscan2
- GFRA3 | c.546C>T p.Y182= | Silent (SNP) | VAF 354/354 reads (100%) | catalogued as COSV51230299, COSV99218589; called by muse, mutect2, varscan2
- GRM8 | c.831A>G p.A277= | Silent (SNP) | VAF 93/282 reads (33%) | catalogued as rs199631296; called by muse, mutect2, varscan2
- HMOX2 | c.135C>T p.H45= | Silent (SNP) | VAF 289/478 reads (60%) | catalogued as rs745794435; called by muse, mutect2, varscan2
- HP1BP3 | c.216G>A p.E72= | Silent (SNP) | VAF 190/381 reads (50%) | called by muse, mutect2, varscan2
- HSPA6 | c.1407C>A p.A469= | Silent (SNP) | VAF 316/723 reads (44%) | called by muse, mutect2
- IRS2 | c.2751C>T p.G917= | Silent (SNP) | VAF 236/728 reads (32%) | catalogued as COSV65480541; called by muse, mutect2, varscan2
- LAS1L | c.1029G>A p.Q343= | Silent (SNP) | VAF 284/519 reads (55%) | called by muse, mutect2, varscan2
- LOX | c.1026A>G p.A342= | Silent (SNP) | VAF 203/203 reads (100%) | called by muse, mutect2, varscan2
- LRRD1 | c.1674C>T p.L558= | Silent (SNP) | VAF 78/122 reads (64%) | called by muse, mutect2, varscan2
- MIDN | c.942G>C p.L314= | Silent (SNP) | VAF 22/682 reads (3%) | called by muse, mutect2
- MMP2 | c.681C>T p.N227= | Silent (SNP) | VAF 167/277 reads (60%) | catalogued as rs558609366, COSV54604672; ClinVar: likely benign; called by muse, mutect2, varscan2
- MRPL16 | c.342C>T p.D114= | Silent (SNP) | VAF 16/484 reads (3%) | called by muse, mutect2
- MUC4 | c.627T>G p.S209= | Silent (SNP) | VAF 34/921 reads (4%) | called by muse, mutect2
- NCOR2 | c.7455C>T p.S2485= | Silent (SNP) | VAF 202/622 reads (32%) | catalogued as rs753152333; called by muse, mutect2, varscan2
- NUP62CL | c.123C>A p.G41= | Silent (SNP) | VAF 252/561 reads (45%) | called by muse, mutect2, varscan2
- OR52N1 | c.873C>T p.N291= | Silent (SNP) | VAF 245/412 reads (59%) | catalogued as rs931990332, COSV100398754; called by muse, mutect2, varscan2
- PAPPA | c.1104G>A p.P368= | Silent (SNP) | VAF 157/329 reads (48%) | catalogued as rs1232382704, COSV60291676; called by muse, mutect2, varscan2
- PCDHA13 | c.2025G>A p.A675= | Silent (SNP) | VAF 303/304 reads (100%) | catalogued as COSV56474821; called by muse, varscan2
- PCNX1 | c.5493T>C p.R1831= | Silent (SNP) | VAF 90/269 reads (33%) | called by muse, mutect2, varscan2
- PLCG1 | c.750C>T p.S250= | Silent (SNP) | VAF 162/736 reads (22%) | catalogued as COSV54815676; called by muse, mutect2, varscan2
- PTPRE | c.1227G>A p.K409= | Silent (SNP) | VAF 322/463 reads (70%) | catalogued as rs768643606; called by muse, mutect2, varscan2
- RGS13 | c.288T>C p.P96= | Silent (SNP) | VAF 78/320 reads (24%) | called by muse, mutect2, varscan2
- RNF144A | c.576C>T p.I192= | Silent (SNP) | VAF 282/430 reads (66%) | catalogued as rs762873762; called by muse, mutect2, varscan2
- RTP1 | c.678G>A p.S226= | Silent (SNP) | VAF 194/586 reads (33%) | catalogued as COSV56617535, COSV56619176; called by muse, mutect2, varscan2
- SH2B1 | c.1809C>T p.H603= | Silent (SNP) | VAF 108/409 reads (26%) | catalogued as COSV59461308; called by muse, mutect2, varscan2
- SKI | c.2062C>T p.L688= | Silent (SNP) | VAF 250/1042 reads (24%) | catalogued as rs1062631; called by muse, mutect2, varscan2
- SLC31A2 | c.201C>T p.I67= | Silent (SNP) | VAF 149/311 reads (48%) | catalogued as rs760428541; called by muse, mutect2, varscan2
- SWI5 | c.399C>T p.H133= | Silent (SNP) | VAF 386/524 reads (74%) | catalogued as rs370235235; called by muse, mutect2, varscan2
- SYPL2 | c.204C>T p.N68= | Silent (SNP) | VAF 266/266 reads (100%) | catalogued as rs557999371, COSV100881557; called by muse, mutect2, varscan2
- TM9SF2 | c.111C>T p.Y37= | Silent (SNP) | VAF 428/692 reads (62%) | called by muse, mutect2, varscan2
- TMEM132C | c.2907C>T p.H969= | Silent (SNP) | VAF 185/542 reads (34%) | catalogued as rs774122401; called by muse, mutect2, varscan2
- TMTC1 | c.546G>A p.S182= (on ENST00000539277 / NM_001193451.2; = p.S74= on NM_175861.3) | Silent (SNP) | VAF 181/270 reads (67%) | catalogued as rs146162779, COSV99760893; called by muse, mutect2, varscan2
- TP63 | c.489C>T p.P163= | Silent (SNP) | VAF 391/639 reads (61%) | catalogued as rs943709826, COSV99285796; called by muse, mutect2, varscan2
- ZMYM4 | c.4530C>T p.F1510= | Silent (SNP) | VAF 247/396 reads (62%) | called by muse, mutect2, varscan2
- ABI3BP | c.*733A>T | 3'UTR (SNP) | VAF 119/176 reads (68%) | called by muse, mutect2, varscan2
- CABP2 | chr11:67524345 C>G | 5'Flank (SNP) | VAF 410/598 reads (69%) | called by muse, mutect2, varscan2
- FNDC3B | c.188-40138G>A | Intron (SNP) | VAF 168/261 reads (64%) | called by muse, mutect2, varscan2
- KCNMA1 | c.378+758C>G | Intron (SNP) | VAF 346/530 reads (65%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-16671C>A | Intron (SNP) | VAF 229/358 reads (64%) | called by muse, mutect2, varscan2
- PPP1CC | c.56-40T>G | Intron (SNP) | VAF 133/452 reads (29%) | called by muse, mutect2, varscan2
- RAB11FIP5 | c.1569-4644G>A | Intron (SNP) | VAF 153/465 reads (33%) | catalogued as rs140694247; called by muse, mutect2, varscan2
- RIMBP2 | c.2362-1898G>A | Intron (SNP) | VAF 464/697 reads (67%) | catalogued as rs972012272; called by muse, mutect2, varscan2
- SYT14 | c.226+2821C>T | Intron (SNP) | VAF 82/219 reads (37%) | catalogued as rs1279975158; called by muse, mutect2, varscan2
- TAF1A | chr1:222590171 C>A | 5'Flank (SNP) | VAF 280/574 reads (49%) | called by muse, mutect2
- ZNF8 | c.66+154G>C | Intron (SNP) | VAF 22/674 reads (3%) | called by muse, mutect2
